Somatic mutation profile of tumor specimen MMRF_2847_1_BM_CD138pos (aliquot MMRF_2847_1_BM_CD138pos_T1_KHS5U_L16580) from MMRF case MMRF_2847, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.7 years (21,063 days).
Specimen MMRF_2847_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90d849ce-3ec3-4fa2-9fe9-267bd35b91fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2847_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2847_1_PB_WBC_C2_KHS5U_L16674; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97889329-0dd9-4882-bb91-22ef4779d286

The open-access MAF lists 98 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 27, Intron 10, Silent 9, 5'UTR 7, Nonsense Mutation 4, 5'Flank 3, 3'Flank 1, In Frame Ins 1, Frame Shift Ins 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.2221G>A p.V741I | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.974); catalogued as rs782677992, COSV61252562; called by muse, mutect2, varscan2
- ANKRD30B | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs755217546, COSV62817501; called by muse, mutect2, varscan2
- COX8C | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); catalogued as COSV56402528; called by muse, varscan2
- CSPP1 | c.3224T>G p.L1075* (on ENST00000676605; = p.L1034* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 50/150 reads (33%) | catalogued as COSV51590933; called by muse, mutect2, varscan2
- DPYSL5 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as rs1037978710, COSV56511022; called by muse, mutect2, varscan2
- GRIN2A | c.4015A>G p.K1339E | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs754686222, COSV58023179; called by muse, mutect2, varscan2
- IGHV2-70 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371561110; called by muse, mutect2, varscan2
- IGLV4-69 | c.198C>G p.Y66* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as rs552922857; called by muse, mutect2, varscan2
- LUZP2 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61209004; called by muse, mutect2, varscan2
- MMP16 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs772275333, COSV54173568, COSV54192724; called by muse, mutect2, varscan2
- OR10H1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 78/120 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs762460753, COSV58472516; called by muse, mutect2, varscan2
- PPOX | c.736A>C p.S246R | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV57091433; called by muse, mutect2, varscan2
- STARD8 | c.1949A>T p.D650V | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99367227; called by muse, mutect2, varscan2
- CHD7 | c.3556A>T p.M1186L | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CYLD | c.421A>T p.K141* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- DUOX2 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ETV6 | c.1192_1193insCAG p.L398delinsPV | In Frame Ins (INS) | VAF 36/144 reads (25%) | called by mutect2, pindel*, varscan2
- FGFR1 | c.1948C>T p.H650Y (on ENST00000447712 / NM_023110.3; = p.H648Y on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGB1 | c.5973G>T p.L1991F | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- HSD17B3 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- IGLV4-60 | c.255T>G p.D85E | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.147); called by muse, varscan2
- KCNE4 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2
- KIAA0825 | c.2446A>C p.T816P | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA5 | c.6338G>T p.G2113V | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NBEA | c.3081dup p.L1028Tfs*9 | Frame Shift Ins (INS) | VAF 58/159 reads (36%) | called by mutect2, pindel, varscan2
- NLRC3 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, varscan2
- NLRC3 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NLRC3 | c.-24-5C>T | Splice Region (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- OPRK1 | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PCDH8 | c.1449C>A p.Y483* | Nonsense Mutation (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- PDPR | c.2090G>C p.G697A | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCZ1 | c.375A>T p.K125N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, varscan2
- PRUNE2 | c.6805G>A p.G2269S | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RAB6B | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- RFTN1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 102/193 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RNF19A | c.1004A>T p.E335V | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC13A4 | c.388T>C p.C130R | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STS | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 42/59 reads (71%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM220 | c.481T>A p.*161Kext*10 | Nonstop Mutation (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- UBALD1 | c.464G>C p.W155S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF48 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AKAP8 | c.933C>T p.Y311= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs201213080; called by muse, mutect2, varscan2
- CHRNA6 | c.921G>A p.L307= | Silent (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- EGR1 | c.102G>A p.K34= | Silent (SNP) | VAF 169/292 reads (58%) | catalogued as rs368477832, COSV53518271; called by muse, varscan2
- HS6ST2 | c.579G>T p.P193= | Silent (SNP) | VAF 58/230 reads (25%) | catalogued as COSV63713032; called by muse, mutect2, varscan2
- LRRC53 | c.207C>T p.I69= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1345524880, COSV53947663; called by muse, mutect2, varscan2
- NLRC3 | c.591C>A p.V197= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, varscan2
- NLRC3 | c.174C>T p.S58= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, varscan2
- TLE3 | c.1392C>A p.P464= | Silent (SNP) | VAF 76/251 reads (30%) | called by muse, mutect2, varscan2
- TUSC3 | c.963G>A p.L321= | Silent (SNP) | VAF 39/63 reads (62%) | called by muse, mutect2, varscan2
- ABCC12 | c.-333G>A | 5'UTR (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3626-656C>T | Intron (SNP) | VAF 119/320 reads (37%) | catalogued as rs368013307; called by muse, mutect2, varscan2
- ALG10B | c.*2572T>C | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, varscan2
- ANTXR2 | c.*4809A>G | 3'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- APOBEC4 | c.-3G>T | 5'UTR (SNP) | VAF 94/217 reads (43%) | called by muse, mutect2, varscan2
- AVL9 | c.*310T>G | 3'UTR (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021491 A>C | 5'Flank (SNP) | VAF 69/186 reads (37%) | called by muse, mutect2, varscan2
- C11orf87 | c.*1152T>A | 3'UTR (SNP) | VAF 30/139 reads (22%) | called by muse, mutect2, varscan2
- CLTC | c.*9_*15del | 3'UTR (DEL) | VAF 91/273 reads (33%) | called by mutect2, pindel, varscan2
- DSG1 | c.*90A>C | 3'UTR (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2
- EIF4A2 | c.29+198T>C | Intron (SNP) | VAF 10/12 reads (83%) | called by muse, varscan2
- ERVV-1 | chr19:53009509 G>C | 5'Flank (SNP) | VAF 54/203 reads (27%) | called by muse, varscan2
- ETV1 | chr7:13894035 G>T | 3'Flank (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- EVA1C | c.634+94T>C | Intron (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- EXOC6B | c.1980+1183T>A | Intron (SNP) | VAF 58/108 reads (54%) | called by muse, mutect2, varscan2
- FAM207A | chr21:44939670 C>A | 5'Flank (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- FJX1 | c.*214del | 3'UTR (DEL) | VAF 49/196 reads (25%) | called by mutect2, pindel, varscan2
- FMO3 | c.*5C>T | 3'UTR (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- GABRA4 | c.*6127C>A | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- GAPDHS | c.-60C>T | 5'UTR (SNP) | VAF 9/287 reads (3%) | called by muse, mutect2
- HACD2 | c.*60A>T | 3'UTR (SNP) | VAF 154/266 reads (58%) | called by muse, mutect2, varscan2
- HGF | c.482+167G>T | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- JHY | c.*82G>A | 3'UTR (SNP) | VAF 45/202 reads (22%) | catalogued as rs940008594; called by muse, mutect2
- LMAN1 | c.*74T>C | 3'UTR (SNP) | VAF 66/132 reads (50%) | called by muse, mutect2, varscan2
- LYNX1 | c.*100C>A | 3'UTR (SNP) | VAF 56/224 reads (25%) | called by muse, mutect2, varscan2
- MCF2L | c.369-195G>A | Intron (SNP) | VAF 15/41 reads (37%) | catalogued as rs952730589; called by muse, mutect2, varscan2
- MLLT3 | c.*3532C>G | 3'UTR (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- MMP16 | c.404+26C>T | Intron (SNP) | VAF 72/258 reads (28%) | called by muse, mutect2, varscan2
- NKX6-3 | c.-309G>C | 5'UTR (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- NT5DC3 | c.*4039T>G | 3'UTR (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- PAX5 | c.-140G>C | 5'UTR (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- PCDH17 | c.*2599G>A | 3'UTR (SNP) | VAF 11/32 reads (34%) | catalogued as rs1030788162; called by muse, mutect2, varscan2
- PDGFB | c.-12C>G | 5'UTR (SNP) | VAF 26/85 reads (31%) | called by muse, mutect2, varscan2
- PDZD8 | c.*4899A>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- PEBP1 | c.*586T>C | 3'UTR (SNP) | VAF 69/124 reads (56%) | called by muse, mutect2, varscan2
- PNO1 | c.*1210A>G | 3'UTR (SNP) | VAF 18/32 reads (56%) | called by muse, varscan2
- PNO1 | c.*1293A>G | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, varscan2
- PTPRC | c.100+1941A>T | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- QDPR | c.629+401T>C | Intron (SNP) | VAF 61/164 reads (37%) | called by muse, mutect2, varscan2
- RAX | c.-114G>A | 5'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SLC36A4 | c.*503G>A | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- SLFN13 | c.*3364C>T | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- SPATA20 | c.313+27G>A | Intron (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- STXBP1 | c.*1297C>T | 3'UTR (SNP) | VAF 70/168 reads (42%) | catalogued as rs1231993921; called by muse, mutect2, varscan2
- TXNRD1 | c.*1822_*1823del | 3'UTR (DEL) | VAF 5/56 reads (9%) | catalogued as rs1491407299; called by pindel, varscan2
- UVSSA | c.*308T>C | 3'UTR (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- WASF2 | c.*1229G>T | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- WSCD2 | c.*577G>T | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
